CCDI case PBCACJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3228ff0b-aeb4-46c3-a96c-b4d098ac084c

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.8 years (653 days).

Biospecimens (3 samples)
- Sample 0DM69J: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM69O: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DM6A0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
